TCGA case TCGA-CM-5863 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cc1d6ad3-b60d-482e-8fa4-0af26823007d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Mucinous adenocarcinoma: ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 60.6 years (22,127 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 457 days (1.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 12; Lymphatic invasion present: No; Non nodal tumor deposits: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 86 days; Days to treatment end: 240 days; Number of cycles: 12; Treatment dose: 21,800 mg; Prescribed dose: 1900; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 86 days; Days to treatment end: 240 days; Number of cycles: 12; Treatment dose: 7,450 mg; Prescribed dose: 650; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin Calcium; Treatment intent type: Adjuvant; Days to treatment start: 86 days; Days to treatment end: 240 days; Number of cycles: 12; Treatment dose: 5,000 mg; Prescribed dose: 650; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 86 days; Days to treatment end: 240 days; Number of cycles: 12; Treatment dose: 1,510 mg; Prescribed dose: 140; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Pegfilgrastim; Treatment intent type: Adjuvant; Days to treatment start: 229 days; Days to treatment end: 229 days; Number of cycles: 1; Treatment dose: 6 mg; Prescribed dose: 6; Prescribed dose units: mg; Route of administration: Subcutaneous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 304 days; Disease response: Tumor Free.
- Days to follow up: 457 days (1.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 4.7 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 103.4 kg; Height: 150 cm; BMI: 46.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CM-5863-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-CM-5863-01A-01-BS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 50; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 20.
- Sample TCGA-CM-5863-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CM-5863-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 4.7; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3, Route of administrations: Route of administration: SC.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Pathology outside specification: Pathology Results off Spec.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 457 days; disease-specific survival: no event (censored), 457 days; progression-free interval: no event (censored), 457 days.
